Somatic mutation profile of tumor specimen TARGET-40-PASYUK-01A (aliquot TARGET-40-PASYUK-01A-01D) from TARGET case TARGET-40-PASYUK, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,931 days).
Specimen TARGET-40-PASYUK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b08c7353-c0a9-41a7-a4e6-3ef3cf3a4aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASYUK-10A (Blood Derived Normal), aliquot TARGET-40-PASYUK-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e4b1a20-a086-45ad-ba71-c921de28ef59

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 4, RNA 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLIS1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs376288261; called by mutect2, varscan2
- GREB1L | c.4508G>A p.R1503Q | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52565927; called by muse, mutect2
- NR4A2 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59893391, COSV59896047; called by muse, mutect2
- ADAM18 | c.1380T>A p.F460L | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FAM205A | c.906G>T p.W302C | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- FAM205A | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- PCDHB15 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SLC4A7 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC6A3 | c.1517A>T p.D506V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, mutect2
- VWF | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZXDA | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 62/281 reads (22%) | called by muse, mutect2, varscan2
- AGFG1 | c.510A>G p.T170= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- NEIL2 | c.348G>A p.E116= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- S100Z | c.201C>T p.D67= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- ZXDA | c.2013G>A p.L671= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as rs1306715053; called by muse, mutect2, varscan2
- ZXDA | c.1071G>A p.E357= | Silent (SNP) | VAF 54/232 reads (23%) | catalogued as COSV100699443; called by muse, mutect2, varscan2
- AC139769.1 | n.214-3751G>A | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- CR1L | c.1414+2338A>T | Intron (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- GOLGA6L17P | n.434-104A>G | Intron (SNP) | VAF 17/269 reads (6%) | catalogued as rs375676975; called by muse, mutect2
- MUCL3 | c.947-882C>A | Intron (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- NBEAP2 | n.933C>T | RNA (SNP) | VAF 5/102 reads (5%) | catalogued as rs201634213; called by muse, mutect2
- POU2F3 | c.*63C>T | 3'UTR (SNP) | VAF 6/52 reads (12%) | catalogued as rs930243845; called by muse, mutect2
